Somatic mutation profile of tumor specimen TCGA-36-2538-01A (aliquot TCGA-36-2538-01A-01D-1526-09) from TCGA case TCGA-36-2538, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 37.5 years (13,681 days).
Specimen TCGA-36-2538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c080022a-431d-4c87-b57f-29857b362fa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2538-10A (Blood Derived Normal), aliquot TCGA-36-2538-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ec3c037-d095-4c93-b4b7-b29bdc3a01ea

The open-access MAF lists 53 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 35, Silent 9, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.482C>A p.A161D | Missense Mutation (SNP) | VAF 102/151 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064795691, COSV52678014, COSV52747111, COSV52839912, COSV53772942; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACVR1C | c.1049C>G p.S350* | Nonsense Mutation (SNP) | VAF 148/285 reads (52%) | catalogued as COSV54645986, COSV54649361; called by muse, mutect2, varscan2
- ANKRD11 | c.1464T>A p.S488R | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV56370331; called by muse, mutect2, varscan2
- BNIP1 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs748038701, COSV51569932; called by muse, mutect2, varscan2
- CD6 | c.1822C>A p.Q608K | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV57838532; called by muse, mutect2, varscan2
- CFAP44 | c.2165T>A p.F722Y | Missense Mutation (SNP) | VAF 127/463 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV55615312; called by muse, mutect2, varscan2
- CTTNBP2 | c.4439G>T p.S1480I | Missense Mutation (SNP) | VAF 170/478 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV50464666; called by muse, mutect2, varscan2
- CXorf65 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 75/133 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52150008; called by muse, mutect2, varscan2
- DBF4 | c.1967A>T p.D656V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV55998666; called by muse, mutect2, varscan2
- DNAH8 | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs1368161666, COSV100546330, COSV59475989; called by muse, mutect2, varscan2
- ERCC3 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 226/673 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs587778275, COSV53429570; ClinVar: not provided; called by muse, mutect2, varscan2
- EXOC2 | c.983T>G p.V328G | Missense Mutation (SNP) | VAF 117/520 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100032286; called by muse, mutect2, varscan2
- GATA5 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53347271; called by muse, varscan2
- ITGAD | c.1523T>C p.V508A | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs752435079, COSV66759906; called by muse, mutect2, varscan2
- KATNB1 | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV65561778; called by muse, varscan2
- KCTD21 | c.616A>G p.K206E | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV60741724; called by muse, mutect2, varscan2
- MED14 | c.2535T>A p.S845R | Missense Mutation (SNP) | VAF 106/211 reads (50%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.974); catalogued as COSV61358359; called by muse, mutect2, varscan2
- MGAT4A | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV53850273; called by muse, mutect2, varscan2
- NCF2 | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 223/633 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62316611; called by muse, mutect2, varscan2
- ODF1 | c.460C>G p.R154G | Missense Mutation (SNP) | VAF 169/428 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV53432366, COSV53433697; called by muse, mutect2, varscan2
- PGGT1B | c.844-1G>C p.X282_splice | Splice Site (SNP) | VAF 34/56 reads (61%) | catalogued as COSV56974952; called by muse, mutect2, varscan2
- PLXDC2 | c.1473G>A p.E491= | Splice Region (SNP) | VAF 136/260 reads (52%) | catalogued as COSV65908413; called by muse, mutect2, varscan2
- POLR3A | c.4072G>C p.G1358R | Missense Mutation (SNP) | VAF 109/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64931976; called by muse, mutect2, varscan2
- QTRT2 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 229/448 reads (51%) | catalogued as rs755530304, COSV55561446; called by muse, mutect2, varscan2
- RAB11FIP5 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50256588; called by muse, mutect2, varscan2
- RB1 | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 162/234 reads (69%) | catalogued as COSV57299669; called by muse, mutect2, varscan2
- SEMA3A | c.1100T>G p.V367G | Missense Mutation (SNP) | VAF 118/349 reads (34%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.936); catalogued as COSV54885749; called by muse, mutect2, varscan2
- SLC38A10 | c.307G>C p.V103L | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55848899; called by muse, mutect2, varscan2
- SPECC1 | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 112/200 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294982557, COSV54965194; called by muse, mutect2, varscan2
- SPRR1B | c.95C>A p.P32Q | Missense Mutation (SNP) | VAF 171/509 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV61068047; called by muse, mutect2, varscan2
- TAS2R1 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV66779353; called by muse, mutect2, varscan2
- TAS2R8 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs769208435, COSV53690420; called by muse, mutect2, varscan2
- TCP11 | c.623A>G p.N208S (on ENST00000512012; = p.N146S on NM_018679.5) | Missense Mutation (SNP) | VAF 93/561 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV55135727; called by muse, mutect2, varscan2
- THRSP | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as COSV55246870; called by muse, mutect2, varscan2
- TKTL1 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 162/246 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.211); catalogued as COSV54214697; called by muse, mutect2, varscan2
- TOMM20 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.358); catalogued as COSV64014279; called by muse, mutect2, varscan2
- TTI1 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100989542; called by muse, mutect2
- TUBE1 | c.983G>A p.S328N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV57890385; called by muse, mutect2, varscan2
- VARS1 | c.3268C>G p.P1090A | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.068); catalogued as COSV63304237, COSV63305069; called by muse, mutect2, varscan2
- ZNF256 | c.1445G>A p.W482* | Nonsense Mutation (SNP) | VAF 67/111 reads (60%) | catalogued as COSV56599534; called by muse, mutect2, varscan2
- ZNF501 | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); catalogued as COSV101247023, COSV101247158; called by muse, mutect2
- GAD2 | c.921-22_929del p.X307_splice | Splice Site (DEL) | VAF 28/81 reads (35%) | called by mutect2, pindel, varscan2
- PKHD1 | c.3739_3757del p.I1247Qfs*50 | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | called by mutect2, pindel, varscan2
- TAF1C | c.1505_1515del p.V502Afs*47 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | called by mutect2, pindel, varscan2
- DCK | c.576G>A p.R192= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV54379697; called by muse, mutect2, varscan2
- GRIN3A | c.1209C>A p.A403= | Silent (SNP) | VAF 13/383 reads (3%) | catalogued as COSV100701298; called by muse, mutect2
- HES1 | c.273G>A p.L91= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV51685549; called by muse, mutect2, varscan2
- JSRP1 | c.258A>T p.G86= | Silent (SNP) | VAF 102/172 reads (59%) | catalogued as COSV55560569; called by muse, mutect2, varscan2
- OTOF | c.2877G>A p.A959= (on ENST00000272371 / NM_194248.3; = p.A212= on NM_004802.4) | Silent (SNP) | VAF 72/284 reads (25%) | catalogued as rs111033424; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SAMD9L | c.3768C>T p.H1256= | Silent (SNP) | VAF 96/228 reads (42%) | catalogued as rs761242992, COSV59084774; called by muse, mutect2, varscan2
- SIRT6 | c.1002G>A p.E334= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV50257251; called by muse, mutect2, varscan2
- ST3GAL6 | c.102G>T p.V34= | Silent (SNP) | VAF 122/421 reads (29%) | catalogued as rs775742532, COSV54579989, COSV54584444; called by muse, mutect2, varscan2
- WNT7B | c.369C>T p.C123= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV59751952, COSV59752038; called by muse, mutect2, varscan2
